Somatic mutation profile of tumor specimen 0DEHPC from CCDI case PBBPUW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.1 years (3,336 days).
Specimen 0DEHPC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e14c11ab-2842-45a9-99c5-cdb4444d35c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEHMZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d212e62-e398-4e5c-9944-8da19fda11b3

The open-access MAF lists 52 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Intron 7, Silent 6, 3'UTR 4, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1, Splice Site 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.1301G>A p.R434Q (on ENST00000272895 / NM_173076.3; = p.R116Q on NM_015657.3) | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as rs745415552, COSV55947973; called by muse, mutect2, varscan2
- ADGRL4 | c.31dup p.S11Ffs*24 | Frame Shift Ins (INS) | VAF 48/155 reads (31%) | catalogued as rs772787365; called by mutect2, pindel, varscan2
- COQ10A | c.604C>T p.H202Y | Missense Mutation (SNP) | VAF 124/469 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV100369865; called by muse, mutect2, varscan2
- FBXO36 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 110/305 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as rs1329496171; called by muse, mutect2, varscan2
- H2AC6 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 80/327 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.791); catalogued as rs1243644116, COSV58415364; called by muse, mutect2, varscan2
- HPS6 | c.746G>A p.W249* | Nonsense Mutation (SNP) | VAF 88/229 reads (38%) | catalogued as COSV54625407, COSV54626940; called by muse, mutect2, varscan2
- INSRR | c.144C>A p.C48* | Nonsense Mutation (SNP) | VAF 102/310 reads (33%) | catalogued as COSV63871757; called by muse, mutect2, varscan2
- KSR2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 108/428 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs775458337, COSV100348676, COSV60389665; called by muse, mutect2, varscan2
- MIER1 | c.1085G>A p.R362H (on ENST00000355356 / NM_001077701.3; = p.R379H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs764657305, COSV100591238; called by muse, mutect2, varscan2
- PLCB4 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53802066; called by muse, mutect2, varscan2
- SLC22A31 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.085); catalogued as rs1270235702; called by muse, mutect2, varscan2
- SLC2A1 | c.657C>G p.N219K | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT tolerated (0.98); PolyPhen benign (0.061); catalogued as COSV65287108; called by muse, mutect2, varscan2
- TSSK2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 149/320 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.332); catalogued as rs745355051; called by muse, mutect2, varscan2
- ABCA9 | c.2222C>A p.A741E | Missense Mutation (SNP) | VAF 276/438 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ANK1 | c.4409C>G p.A1470G | Missense Mutation (SNP) | VAF 143/787 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BCLAF1 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CSMD1 | c.9246del p.D3083Tfs*38 (on ENST00000520002; = p.D3082Tfs*38 on NM_033225.6) | Frame Shift Del (DEL) | VAF 171/1144 reads (15%) | called by mutect2, pindel, varscan2
- CUL4B | c.2543A>G p.Y848C | Missense Mutation (SNP) | VAF 114/139 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB42 | c.337G>T p.V113F (on ENST00000441366 / NM_001114134.2; = p.V143F on NM_000119.3) | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ETNK2 | c.1042G>C p.A348P | Missense Mutation (SNP) | VAF 159/424 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- INSC | c.731G>T p.R244I | Missense Mutation (SNP) | VAF 145/572 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- LHCGR | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MFSD10 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MUC4 | c.13589G>T p.R4530L (on ENST00000463781 / NM_018406.7; = p.R294L on NM_004532.6) | Missense Mutation (SNP) | VAF 180/354 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MYO6 | c.1935C>A p.N645K | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NPEPL1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 195/463 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM27 | c.1303C>A p.H435N | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- RNF41 | c.363-1G>T p.X121_splice | Splice Site (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- SGO2 | c.2017T>G p.S673A | Missense Mutation (SNP) | VAF 147/370 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SOS1 | c.3068C>G p.P1023R | Missense Mutation (SNP) | VAF 96/238 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TIE1 | c.360C>A p.H120Q | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- UBASH3B | c.1748G>T p.C583F | Missense Mutation (SNP) | VAF 265/580 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ARHGEF19 | c.2298G>T p.V766= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- CSF3R | c.1860C>T p.T620= | Silent (SNP) | VAF 134/351 reads (38%) | catalogued as rs762585804; called by muse, mutect2, varscan2
- DUSP28 | c.183C>T p.P61= | Silent (SNP) | VAF 165/395 reads (42%) | catalogued as rs1209709198; called by muse, mutect2, varscan2
- TMBIM6 | c.16C>A p.R6= | Silent (SNP) | VAF 90/287 reads (31%) | catalogued as COSV99920577; called by mutect2, varscan2
- USP6 | c.3510C>T p.S1170= | Silent (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- XPO6 | c.264T>C p.R88= | Silent (SNP) | VAF 100/281 reads (36%) | catalogued as rs1477392437; called by muse, mutect2, varscan2
- ABCA7 | c.4764+20G>A | Intron (SNP) | VAF 73/200 reads (37%) | catalogued as rs367970821; called by muse, mutect2, varscan2
- ACSM5 | c.-6G>A | 5'UTR (SNP) | VAF 43/134 reads (32%) | catalogued as rs1179445419, COSV100089517; called by muse, mutect2, varscan2
- ANAPC11 | c.110-436T>A | Intron (SNP) | VAF 77/392 reads (20%) | called by muse, mutect2, varscan2
- DUSP28 | c.393+50G>C | Intron (SNP) | VAF 27/75 reads (36%) | catalogued as rs935202834; called by muse, mutect2, varscan2
- FAM25C | c.*4C>A | 3'UTR (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- GDF11 | c.*64C>A | 3'UTR (SNP) | VAF 30/84 reads (36%) | called by mutect2, varscan2
- HPD | c.93+31C>A | Intron (SNP) | VAF 53/193 reads (27%) | called by muse, mutect2, varscan2
- KIFC2 | c.1004-21C>A | Intron (SNP) | VAF 39/377 reads (10%) | called by muse, mutect2, varscan2
- MYL6 | chr12:56161475 T>C | 3'Flank (SNP) | VAF 59/212 reads (28%) | called by muse, mutect2, varscan2
- OSCP1 | c.546+3408G>T | Intron (SNP) | VAF 76/204 reads (37%) | called by muse, mutect2, varscan2
- PRR12 | c.52-117C>A | Intron (SNP) | VAF 65/160 reads (41%) | catalogued as rs1338828478, COSV101330788, COSV69817855; called by muse, mutect2, varscan2
- PSTPIP1 | c.*9C>T | 3'UTR (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1379G>A | RNA (SNP) | VAF 52/147 reads (35%) | catalogued as rs766234936; called by muse, mutect2, varscan2
- TEX15 | c.*11C>A | 3'UTR (SNP) | VAF 63/507 reads (12%) | called by muse, mutect2, varscan2
